Somatic mutation profile of tumor specimen ALCH-B766-TTP1-A (aliquot ALCH-B766-TTP1-A-1-0-D-A96E-47) from ALCHEMIST case ALCH-B766, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,060 days).
Specimen ALCH-B766-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ed9de71-4ec4-4749-a6b8-ff20bede1449.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B766-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B766-NB1-A-1-0-D-A96Q-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c55c2d61-81e9-4357-8459-e7d1015a56bc

The open-access MAF lists 51 somatic variants for this specimen: 32 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, 5'UTR 2, Nonsense Mutation 2, 5'Flank 1, Intron 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: likely pathogenic; called by muse, mutect2
- ABCD1 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as CM078360; called by muse, mutect2, varscan2
- ADHFE1 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1157213435; called by muse, mutect2, varscan2
- FGD6 | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs774885571, COSV59696376; called by muse, mutect2, varscan2
- FNTB | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV99863103; called by muse, mutect2, varscan2
- MPV17 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs768617578; called by muse, mutect2, varscan2
- PCDHGA8 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as rs1026935408; called by muse, mutect2
- PLEC | c.4580C>T p.A1527V (on ENST00000322810 / NM_201380.4; = p.A1417V on NM_000445.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs781873089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC51A | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs139191241; called by muse, mutect2, varscan2
- SPATA31A6 | c.3693C>A p.H1231Q | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.381); catalogued as rs1472755043; called by muse, mutect2
- SPTBN5 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as rs1231557050, COSV58015879; called by muse, varscan2
- URB1 | c.1022T>G p.L341W | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456935333; called by muse, mutect2
- WWP2 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403287375; called by muse, mutect2, varscan2
- ADAM15 | c.1498T>C p.C500R | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BX276092.9 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CLEC16A | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- F8 | c.5874G>C p.R1958S | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- FMNL2 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FRMPD1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- HECW1 | c.3074A>T p.E1025V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGHV3-73 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP1A | c.7558G>A p.E2520K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RAB3GAP1 | c.822T>A p.D274E | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SETDB1 | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC25A13 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- SLFN12 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- SPINK14 | c.89_91dup p.W30_P31insR | In Frame Ins (INS) | VAF 65/161 reads (40%) | called by mutect2, pindel, varscan2
- SPTB | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2
- SSC5D | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- TTLL13P | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VEZF1 | c.1026_1049del p.Q347_Q354del | In Frame Del (DEL) | VAF 8/100 reads (8%) | called by mutect2, pindel
- WDR7 | c.2557C>G p.Q853E | Missense Mutation (SNP) | VAF 5/146 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2
- AMER2 | c.1611G>A p.S537= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV63435945; called by muse, mutect2, varscan2
- ARF6 | c.114G>A p.S38= | Silent (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2
- ATRIP | c.1242T>A p.P414= | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- CHD5 | c.3585C>T p.F1195= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs368909187; called by muse, mutect2, varscan2
- CKAP2 | c.1626A>G p.V542= (on ENST00000378037 / NM_001098525.2; = p.V541= on NM_018204.5) | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as rs1461547603; called by muse, mutect2, varscan2
- CSTF3 | c.72A>G p.K24= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- FGA | c.1758C>T p.S586= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- GOLGB1 | c.9273A>C p.A3091= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- HYDIN | c.7680G>A p.K2560= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV59256912; called by muse, mutect2, varscan2
- MROH2A | c.459G>T p.L153= | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- P2RY2 | c.222C>T p.H74= | Silent (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- PARD3B | c.2088G>A p.P696= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as rs552311482; called by muse, mutect2, varscan2
- PPP2R2C | c.633G>A p.V211= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- TENM4 | c.4722C>T p.N1574= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as COSV53605282; called by muse, mutect2, varscan2
- WDR37 | c.1140C>T p.N380= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs761163329, COSV54127520; called by muse, mutect2, varscan2
- DNAJC21 | c.-10C>G | 5'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- GRAMD4 | c.-56G>T | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- MFSD9 | c.253+262G>A | Intron (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- VASH2 | chr1:212950669 C>A | 5'Flank (SNP) | VAF 23/82 reads (28%) | called by mutect2, varscan2
